Somatic mutation profile of tumor specimen TCGA-4K-AA1G-01A (aliquot TCGA-4K-AA1G-01A-11D-A435-10) from TCGA case TCGA-4K-AA1G, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 34.8 years (12,696 days).
Specimen TCGA-4K-AA1G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d18eda00-d702-461e-be87-c84a0cf4c135.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4K-AA1G-10A (Blood Derived Normal), aliquot TCGA-4K-AA1G-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e66aa4cc-102f-48a5-90c3-d0da54fb26c2

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 37/53 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- LDLR | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1442411392; called by muse, mutect2
- SELENOI | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs1307816256; called by muse, mutect2, varscan2
- SLC35E3 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs974781179; called by muse, mutect2, varscan2
- ACOD1 | c.891G>C p.E297D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPS2 | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DYNC1LI1 | c.777C>G p.Y259* | Nonsense Mutation (SNP) | VAF 51/230 reads (22%) | called by muse, mutect2, varscan2
- FBXO16 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- FBXO2 | c.633C>G p.S211R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, varscan2
- PIK3C2A | c.4081C>G p.Q1361E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RBM23 | c.617C>A p.S206Y (on ENST00000359890 / NM_001077351.2; = p.S190Y on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZBTB10 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD46 | c.942C>T p.A314= | Silent (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- SETD1A | c.540T>C p.Y180= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- SIAE | c.891C>T p.I297= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs780782832, COSV55015100; called by muse, mutect2, varscan2
